Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB3C, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB3C-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

ICD-O-3
Sarcoma, synovial monophase
fibrous 9041/3
Site: Popliteal space 49.2
JW 5/14/14

Clinical Diagnosis & History:

Patient with cytology proven sarcoma of right popliteal area consistent with synovial sarcoma.

Specimens Submitted:

- 1: SP: Biopsy right popliteal mass (fs)
- 2: SP: Proximal margin right popliteal mass (fs)
- 3: SP: Distal margin right popliteal mass (fs)
- 4: SP: Medial margin right popliteal mass (fs)
- 5: SP: Lateral margin right popliteal mass (fs)
- 6: SP: Deep margin right popliteal mass (fs)
- 7: SP: Right popliteal mass

DIAGNOSIS:

- 1) SOFT TISSUE, RIGHT POPLITEAL SPACE; BIOPSY:
- SYNOVIAL SARCOMA.
- 2) SOFT TISSUE, RIGHT POPLITEAL SPACE, PROXIMAL MARGIN; BIOPSY:
- FIBROADIPOSE TISSUE, NO TUMOR SEEN.
- 3) SOFT TISSUE, RIGHT POPLITEAL SPACE, DISTAL MARGIN; BIOPSY:
- SKELETAL MUSCLE, NO TUMOR SEEN.
- 4) SOFT TISSUE, RIGHT POPLITEAL SPACE, MEDIAL MARGIN; BIOPSY:
- SKELETAL MUSCLE AND FAT, NO TUMOR SEEN.
- 5) SOFT TISSUE, RIGHT POPLITEAL SPACE, LATERAL MARGIN; BIOPSY:
- FIBROADIPOSE TISSUE, NO TUMOR SEEN.
- 6) SOFT TISSUE, RIGHT POPLITEAL SPACE, DEEP MARGIN; BIOPSY:
- FIBROCONNECTIVE TISSUE, NO TUMOR SEEN.
- 7) SOFT TISSUE, RIGHT POPLITEAL SPACE; EXCISION:
- HIGH GRADE MONOPHASIC SYNOVIAL SARCOMA, POORLY DIFFERENTIATED
SUBTYPE, INVOLVING SKELETAL MUSCLE.
- TUMOR SIZE: 7.1 x 6.9 x 5.3 CM.
- TUMOR SHOWS PREDOMINANTLY A SMALL BLUE ROUND CELL MORPHOLOGY CONSISTENT
WITH A POORLY DIFFERENTIATED SYNOVIAL SARCOMA.
- TUMOR SHOWS AREAS OF NECROSIS (ESTIMATED GROSSLY AS 20%).

** Continued on next page **

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 6
- TUMOR IS PRESENT 0.1 CM FROM THE LATERAL MARGIN, LESS THAN 0.1 CM FROM THE ANTERIOR AND POSTERIOR MARGINS.
- ONE BENIGN LYMPH NODE SEEN (0/1).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "biopsy, right popliteal mass " and consists of multiple tan-white soft tissue fragments ranging from 0.2 cm up to 0.5 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

2). The specimen is received fresh for frozen section consultation, labeled "proximal margin, right popliteal mass" and consists of a fibrofatty soft tissue fragment measuring 1.0 cm in greatest dimension, which is entirely submitted for frozen section consultation.

Summary of sections:
FSC -- frozen section control

3). The specimen is received fresh for frozen section consultation, labeled "distal margin, right popliteal mass" and consists of an irregular portion of skeletal muscle measuring 1.0 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

** Continued on next page **

[page 3 of 6]
4). The specimen is received fresh for frozen section consultation, labeled "medial margin, right popliteal mass" and consists of an irregular portion of skeletal muscle measuring 1.0 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

5). The specimen is received fresh for frozen section consultation, labeled "lateral margin, right popliteal mass" and consists of an irregular portion of fibrofatty soft tissue measuring 0.9 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

6). The specimen is received fresh for frozen section consultation, labeled "deep margin, right popliteal mass" and consists of an irregular portion of fibrofatty soft tissue measuring 1.1 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:
FSC -- frozen section control

7). The specimen is received labeled "right popliteal mass" and is comprised of a portion of soft tissue measuring 9.5 x 9.5 x 7 cm and is oriented by four sutures: black stitch inferior, blue stitch posterior, white stitch biopsy defect, green stitch lateral. The external surface is covered by numerous staples and is comprised of muscle, tendinous tissue, fat, smooth glistening tissue, and cauterized irregular tissue. The margins of resection are inked as follows inferior black, posterior blue, lateral green, anterior yellow, superior red, and medial orange. The specimen is serially sectioned revealing a 7.1 x 6.9 x 5.3 cm well-circumscribed mass with a variegated and friable cut surface, including areas of tan-pink homogenous tissue, necrosis (20%) and cystic degeneration. Lateral wall of the specimen is entirely occupied by a 4.5 cm diameter cyst showing a red-tan irregular and necrotic lining. Portion of tissue submitted for TPS. The specimen is photographed. Representative sections are submitted.

Summary of sections:
S-superior margin
I-inferior margin
M-medial margin
L-lateral margin

** Continued on next page **

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

----- Page 4 of 6

A- anterior margin
P-posterior margin
T-tumor

Summary of Sections:

Part 1: SP: Biopsy right popliteal mass (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 2: SP: Proximal margin right popliteal mass (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 3: SP: Distal margin right popliteal mass (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 4: SP: Medial margin right popliteal mass (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 5: SP: Lateral margin right popliteal mass (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 6: SP: Deep margin right popliteal mass (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 7: SP: Right poplital mass

Block	Sect.	Site	PCs
3	A		3
2	I		2
2	L		2
1	M		1
3	P		3
1	S		1
5	T		5

Intraoperative Consultation:

** Continued on next page **

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Page 5 of 6

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Biopsy right popliteal mass (fs)
: SARCOMA
PERMANENT DIAGNOSIS: SAME
2. FROZEN SECTION DIAGNOSIS: SP: Proximal margin right popliteal mass (fs)
: BENIGN
PERMANENT DIAGNOSIS: SAME
3. FROZEN SECTION DIAGNOSIS: SP: Distal margin right popliteal mass (fs)
: BENIGN
PERMANENT DIAGNOSIS: SAME
4. FROZEN SECTION DIAGNOSIS: SP: Medial margin right popliteal mass (fs)
: BENIGN
PERMANENT DIAGNOSIS: SAME
5. FROZEN SECTION DIAGNOSIS: SP: Lateral margin right popliteal mass (fs)
: BENIGN
PERMANENT DIAGNOSIS: SAME
6. FROZEN SECTION DIAGNOSIS: SP: Deep margin right popliteal mass (fs)
: BENIGN
PERMANENT DIAGNOSIS: SAME

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Biopsy right popliteal mass (fs)
: SARCOMA
PERMANENT DIAGNOSIS: SAME
2. FROZEN SECTION DIAGNOSIS: SP: Proximal margin right popliteal mass (fs)
: BENIGN
PERMANENT DIAGNOSIS: SAME
3. FROZEN SECTION DIAGNOSIS: SP: Distal margin right popliteal mass (fs)
: BENIGN
PERMANENT DIAGNOSIS: SAME
4. FROZEN SECTION DIAGNOSIS: SP: Medial margin right popliteal mass (fs)
: BENIGN
PERMANENT DIAGNOSIS: SAME

** Continued on next page **

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

----- Page 6 of 6

5. FROZEN SECTION DIAGNOSIS: SP: Lateral margin right popliteal
mass (fs) : BENIGN
PERMANENT DIAGNOSIS: SAME
6. FROZEN SECTION DIAGNOSIS: SP: Deep margin right popliteal mass
(fs) : BENIGN
PERMANENT DIAGNOSIS: SAME

** End of Report **

Criteria	lw 1/22/14	Yes	No

Source: NCI Genomic Data Commons file 0ae0ac86-0e27-41c3-a232-1750335d9cfd (TCGA-DX-AB3C.B7268006-6BDF-4A42-B9EA-01E7F9797949.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).